Somatic mutation profile of tumor specimen TCGA-FD-A3B7-01A (aliquot TCGA-FD-A3B7-01A-31D-A20D-08) from TCGA case TCGA-FD-A3B7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 66.4 years (24,245 days).
Specimen TCGA-FD-A3B7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57fe0120-ab19-4a49-b624-91ea7fdc3bd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3B7-10A (Blood Derived Normal), aliquot TCGA-FD-A3B7-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80932c1f-8b98-492e-a3c2-322220311830

The open-access MAF lists 73 somatic variants for this specimen: 57 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 12, Nonsense Mutation 6, RNA 2, Frame Shift Ins 1, Splice Site 1, Intron 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 30/108 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD34A | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV60161192; called by muse, mutect2, varscan2
- ASGR1 | c.633G>A p.W211* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | catalogued as COSV99352616; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV52269990; called by muse, mutect2
- AXDND1 | c.58A>G p.K20E | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV62643766; called by muse, mutect2, varscan2
- BCAS3 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs766394914, COSV66771518; called by mutect2, varscan2
- BPTF | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs771413164, COSV58839331; called by muse, mutect2, varscan2
- C8orf86 | n.723-1G>C | Splice Site (SNP) | VAF 12/90 reads (13%) | catalogued as COSV63935457; called by muse, varscan2
- CAD | c.226T>G p.F76V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as COSV53028027; called by muse, varscan2
- CDH10 | c.1612C>G p.Q538E | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV52574897, COSV52584423; called by muse, mutect2
- CDH6 | c.1981G>C p.D661H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763159274, COSV54068419, COSV54071836; called by muse, mutect2, varscan2
- CELSR1 | c.1628C>G p.P543R | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs749866727, COSV53092446; called by muse, mutect2, varscan2
- COPS2 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV54644157; called by muse, mutect2
- CR1 | c.4175G>A p.R1392H | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); catalogued as rs200621891, COSV65462323; called by muse, mutect2
- CSNK1A1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV55795360; called by muse, mutect2, varscan2
- DHX34 | c.3289G>A p.G1097R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV60895889; called by muse, mutect2, varscan2
- DNAH10 | c.12805G>A p.E4269K (on ENST00000409039; = p.E4208K on NM_207437.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs1347626749, COSV53020176; called by muse, mutect2, varscan2
- E2F8 | c.422T>G p.I141S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51464258; called by muse, mutect2, varscan2
- GJC1 | c.1136A>C p.N379T | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57911587; called by muse, mutect2
- GLDN | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59090744; called by muse, mutect2, varscan2
- GSTM5 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56658614; called by muse, mutect2
- HECW1 | c.3359T>C p.V1120A | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV67831808; called by muse, mutect2, varscan2
- IL33 | c.234A>T p.R78S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV67343243; called by muse, mutect2, varscan2
- IQSEC3 | c.1495G>A p.V499I (on ENST00000538872 / NM_001170738.2; = p.V196I on NM_015232.1) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as COSV58285958; called by muse, mutect2
- KCNG3 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as COSV60149698; called by muse, mutect2, varscan2
- KIF1C | c.392del p.S131Mfs*14 | Frame Shift Del (DEL) | VAF 26/136 reads (19%) | catalogued as COSV57904989; called by mutect2, pindel, varscan2
- KIFC1 | c.509A>G p.Q170R | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.4); catalogued as COSV65737649; called by muse, mutect2
- LTN1 | c.4115A>G p.K1372R | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.348); catalogued as COSV63734048; called by muse, mutect2, varscan2
- MDGA2 | c.2732A>C p.H911P (on ENST00000399232 / NM_001113498.2; = p.H613P on NM_182830.4) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62097254; called by muse, mutect2, varscan2
- MRTFB | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs1487554289, COSV57958827; called by muse, mutect2, varscan2
- MUC16 | c.40618A>C p.K13540Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as COSV66693252; called by muse, varscan2
- NGF | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384874552, COSV65687959; called by muse, mutect2
- NLRP4 | c.1742T>C p.I581T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as rs761145524, COSV56715834; called by muse, mutect2, varscan2
- NR2F1 | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV59068745; called by muse, mutect2, varscan2
- NSMCE1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.486); catalogued as COSV63864409; called by muse, mutect2, varscan2
- OR13C8 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV58611422; called by muse, mutect2, varscan2
- OR2T4 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63543406; called by muse, mutect2
- OR8H3 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV57909539; called by muse, mutect2, varscan2
- PCSK5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as COSV65090504; called by muse, mutect2, varscan2
- PI4KB | c.1802T>G p.L601R (on ENST00000368873 / NM_001369623.1; = p.L613R on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55018531; called by muse, mutect2, varscan2
- RB1 | c.2293A>T p.K765* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV57303249; called by muse, mutect2, varscan2
- SERPINB9 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV66233643; called by muse, mutect2, varscan2
- SEZ6L | c.2338G>A p.V780M | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs375640180; called by muse, mutect2, varscan2
- SHANK2 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53602815; called by muse, mutect2
- SLC35G3 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 46/197 reads (23%) | catalogued as rs762545351; called by muse, mutect2, varscan2
- SLC9A4 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs549137706, COSV54835184; called by muse, mutect2, varscan2
- SMAD4 | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61689562, COSV61695800; called by muse, mutect2, varscan2
- SPTA1 | c.1805A>T p.K602I | Missense Mutation (SNP) | VAF 114/338 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.115); catalogued as COSV63754830; called by muse, mutect2, varscan2
- TAS2R40 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV68818436; called by muse, mutect2
- TIGD2 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.975); catalogued as COSV57647209; called by muse, mutect2, varscan2
- UTP14C | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73000701; called by muse, mutect2
- ZBTB7B | c.1164G>T p.K388N (on ENST00000292176; = p.K422N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52692111, COSV52692260; called by muse, mutect2, varscan2
- CDKN1A | c.133dup p.A45Gfs*3 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.1502C>G p.S501C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- MYNN | c.1543A>T p.K515* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- RC3H1 | c.2659A>T p.K887* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- ZNF84 | c.1746G>C p.Q582H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.101); called by muse, mutect2
- AC006059.2 | c.1314G>A p.L438= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV59606147; called by muse, mutect2, varscan2
- BAZ2A | c.462C>G p.T154= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV51638208; called by muse, mutect2, varscan2
- CFAP65 | c.1968C>T p.V656= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs889158751, COSV58562266; called by muse, mutect2, varscan2
- CHAF1B | c.786A>C p.V262= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV58440350; called by muse, mutect2
- H1-6 | c.438T>C p.T146= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV58090722; called by muse, mutect2, varscan2
- HCN4 | c.2268G>T p.A756= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs781114942, COSV56082174; called by muse, mutect2, varscan2
- HDAC10 | c.546C>G p.L182= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV53133581; called by muse, mutect2
- HID1 | c.1377C>T p.A459= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1478156522, COSV59351714; called by muse, mutect2, varscan2
- RB1CC1 | c.1488C>T p.Y496= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs1214148371, COSV50252803; called by muse, mutect2, varscan2
- SPEN | c.8091G>C p.V2697= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV101005156, COSV65363379; called by mutect2, varscan2
- SYT5 | c.24G>T p.P8= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1326030696, COSV54746487; called by muse, mutect2, varscan2
- TOM1L1 | c.114C>A p.I38= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV61947977, COSV61948018, COSV61948488; called by muse, mutect2
- C8orf86 | n.794G>A | RNA (SNP) | VAF 42/177 reads (24%) | catalogued as COSV100817585, COSV63935450; called by muse, varscan2
- IKBIP | c.297+8017A>T | Intron (SNP) | VAF 24/116 reads (21%) | catalogued as COSV54489973; called by muse, mutect2, varscan2
- MIR34A | n.45G>A | RNA (SNP) | VAF 59/389 reads (15%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280404 G>A | 5'Flank (SNP) | VAF 14/41 reads (34%) | catalogued as rs1484411483; called by muse, mutect2, varscan2
